Somatic mutation profile of tumor specimen MP2PRT-PAUCLB-TBP1-A (aliquot MP2PRT-PAUCLB-TBP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUCLB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (857 days).
Specimen MP2PRT-PAUCLB-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46b83176-0c1f-48e5-8dd4-bc077af91f9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUCLB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUCLB-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5df2919a-c0ba-40ef-8efc-9a75d9feb808

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 50/327 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DDX3X | c.850G>A p.E284K (on ENST00000399959; = p.E285K on NM_001356.5) | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67864532; called by muse, mutect2, varscan2
- DMGDH | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as rs369589026; called by muse, mutect2
- EPB41L1 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 105/335 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs762619496; called by muse, mutect2, varscan2
- ERICH3 | c.3679G>A p.V1227M | Missense Mutation (SNP) | VAF 137/470 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV58603194; called by muse, mutect2, varscan2
- FAM189A2 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 79/368 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369333590; called by muse, mutect2, varscan2
- GRIN1 | c.459G>C p.E153D | Missense Mutation (SNP) | VAF 90/394 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SP3 | c.547C>A p.Q183K | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DNAH11 | c.8820C>T p.S2940= | Silent (SNP) | VAF 60/276 reads (22%) | catalogued as rs377417038; called by muse, mutect2, varscan2
- SHROOM2 | c.3741C>A p.I1247= | Silent (SNP) | VAF 167/480 reads (35%) | called by muse, mutect2, varscan2
- ZDHHC24 | c.594C>T p.F198= | Silent (SNP) | VAF 95/385 reads (25%) | catalogued as rs527917626, COSV100130582; called by muse, mutect2, varscan2
